Gene-level copy-number profile of tumor specimen HCM-BROD-0959-C18-06A from HCMI case HCM-BROD-0959-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: G4; Age at diagnosis: 66.3 years (24,234 days).
Specimen HCM-BROD-0959-C18-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f15eb819-b261-4790-82e6-d7d61b17d262.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0959-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/09330a27-fe11-4308-9f22-da1bb959624e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 4,487; copy number 2: 28,568; copy number 3: 11,703; copy number 4: 10,388; copy number 5: 2,088; copy number 6: 832; copy number 7: 287; copy number 8: 1; copy number 9: 3; copy number 10: 11.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,605,847–57,606,206, 1 gene (within-gene range 0–2): RPS20P5.
- chr3:30,606,601–30,894,765, 4 genes (within-gene range 0–2): TGFBR2, AC096921.1, AC096921.2, GADL1.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr18:72,536,680–72,881,399, 7 genes: CBLN2, HNRNPA1P11, NETO1, AC023301.1, RNA5SP460, MIR548AV, AC091138.1.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,222 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:184,593,577–185,547,818, 4 genes, copy number 6–7: AC096667.1, ZNF804A, RPL23AP33, ELF2P4.
- chr2:185,661,774–185,661,906, 1 gene, copy number 6: U8.
- chr2:198,882,573–200,008,540, 15 genes, copy number 6: AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1, SATB2-AS1, LINC01877, SEPHS1P6, FTCDNL1, AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1.
- chr2:207,074,137–208,222,625, 39 genes, copy number 7: KLF7, MIR2355, KLF7-IT1, MYOSLID, MIR7845, AC007879.1, AC007879.3, AC007879.5, AC007879.2, AC007879.4, AC009226.1, LINC01802, MIR1302-4, CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17, CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB, CRYGA, C2orf80, RPSAP27, TPT1P2.
- chr6:55,939,790–78,946,440, 214 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:80,972,516–105,399,308, 457 genes, copy number 5–6 (broad region; genes not listed).
- chr8:37,600,537–38,060,365, 19 genes, copy number 6–7: AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1.
- chr8:123,497,889–126,522,360, 58 genes, copy number 6: FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3.
- chr8:126,556,323–127,419,050, 1 gene, copy number 5 (within-gene range 4–5): PCAT1.
- chr8:127,072,694–145,066,685, 330 genes, copy number 5–7 (broad region; genes not listed).
- chr9:63,299,453–63,385,117, 3 genes, copy number 9 (within-gene range 4–9): BMS1P10, AQP7P1, AL845321.1.
- chr9:68,328,308–69,274,615, 18 genes, copy number 6 (within-gene range 2–6): PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2.
- chr9:73,151,865–73,170,393, 1 gene, copy number 5: ANXA1.
- chr12:12,310–16,277,685, 526 genes, copy number 5 (broad region; genes not listed).
- chr12:62,935,701–67,729,475, 108 genes, copy number 6–10 (broad region; genes not listed).
- chr13:18,467,172–49,495,003, 603 genes, copy number 5–6 (broad region; genes not listed).
- chr13:96,090,839–114,337,626, 271 genes, copy number 5 (broad region; genes not listed).
- chr16:67,518,418–68,594,424, 69 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:8,406,761–27,247,188, 334 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:29,048,620–29,548,241, 4 genes, copy number 5: RNU6-408P, AC105245.1, AC074237.1, AC117569.1.
- chr19:13,731,760–16,245,906, 146 genes, copy number 6–7 (broad region; genes not listed).
- chr21:8,680,538–8,680,934, 1 gene, copy number 8: CR381572.2.

Autosomal genes at a single copy (total copy number 1): 2,143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
